Gene-level copy-number profile of tumor specimen TCGA-YL-A8S9-01A from TCGA case TCGA-YL-A8S9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,204 days).
Specimen TCGA-YL-A8S9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a76269f1-dda8-489e-9a1b-44c146a3bbc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A8S9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f30a5bc-3171-40ec-bbde-6af6868dbc60

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,508; copy number 2: 51,364; copy number 3: 890; copy number 4: 463; copy number 6: 1,565; copy number 16: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A8S9-01A-11D-A376-01): tumor purity 0.95, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,595 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,896,946–145,066,685, 1,564 genes, copy number 6–16 (within-gene range 1–16) (broad region; genes not listed).
- chr16:46,469,341–47,464,149, 31 genes, copy number 6 (within-gene range 1–6): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 3,121. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
